Somatic mutation profile of tumor specimen 0DNMAT from CCDI case PBCBTY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,428 days).
Specimen 0DNMAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8040af58-21c4-4877-bcac-c748817454cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0edf885a-1bd2-4e53-b567-0456016973a5

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Intron 3, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.2421C>G p.N807K (on ENST00000357195 / NM_001282237.2; = p.N736K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs888230251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187814086, COSV53323190; called by muse, mutect2, varscan2
- ARMCX2 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as rs1556071796; called by muse, mutect2, varscan2
- ATRX | c.2753C>A p.T918N | Missense Mutation (SNP) | VAF 80/510 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV64875739; called by muse, mutect2, varscan2
- C10orf143 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1210259266; called by muse, mutect2
- CCDC34 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 93/783 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147823135; called by muse, mutect2, varscan2
- CLEC3B | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs920902974, COSV56109503; called by muse, mutect2, varscan2
- NBAS | c.5269G>A p.E1757K | Missense Mutation (SNP) | VAF 261/660 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.121); catalogued as rs773927038, COSV55711890; called by muse, mutect2, varscan2
- NLRP12 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs370612027; ClinVar: uncertain significance; called by muse, mutect2
- SIGLEC8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200891335, COSV100367463; called by muse, mutect2, varscan2
- BBX | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 21/872 reads (2%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- C3 | c.1654dup p.W552Lfs*37 | Frame Shift Ins (INS) | VAF 20/162 reads (12%) | called by mutect2, varscan2
- COP1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 162/1056 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CYP39A1 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 63/586 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSC3 | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 68/829 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FAF2 | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 21/728 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2
- FAM3A | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM76A | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 123/483 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- HIPK2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAGEB18 | c.516del p.Y173Tfs*8 | Frame Shift Del (DEL) | VAF 86/302 reads (28%) | called by mutect2, varscan2
- MEPE | c.1096C>G p.H366D | Missense Mutation (SNP) | VAF 22/715 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RBM7 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP7A | c.4332A>T p.S1444= | Silent (SNP) | VAF 38/300 reads (13%) | called by muse, mutect2, varscan2
- CENPN | c.480C>T p.Y160= | Silent (SNP) | VAF 219/325 reads (67%) | catalogued as rs745762294, COSV55142412; called by muse, mutect2, varscan2
- FAM151A | c.111G>A p.R37= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- MYCBP2 | c.9849A>G p.Q3283= (on ENST00000357337; = p.Q3321= on NM_015057.5) | Silent (SNP) | VAF 20/706 reads (3%) | called by muse, mutect2
- POU2F2 | c.1263C>A p.G421= (on ENST00000526816 / NM_001207025.3; = p.G405= on NM_002698.5) | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- SHROOM1 | c.2535G>A p.P845= (on ENST00000378679 / NM_001172700.2; = p.P840= on NM_133456.2) | Silent (SNP) | VAF 29/292 reads (10%) | catalogued as rs1345272540; called by muse, mutect2, varscan2
- CCDC116 | c.1203+183C>A | Intron (SNP) | VAF 30/214 reads (14%) | catalogued as rs1452621509; called by muse, mutect2, varscan2
- DNAH14 | c.9205+6208C>A | Intron (SNP) | VAF 62/1244 reads (5%) | catalogued as rs1001467174; called by muse, mutect2
- RASSF4 | c.807+38G>T | Intron (SNP) | VAF 72/163 reads (44%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895841 G>A | 5'Flank (SNP) | VAF 45/196 reads (23%) | catalogued as rs149602220, COSV60003636; called by muse, mutect2, varscan2
